Somatic mutation profile of tumor specimen TCGA-D8-A4Z1-01A (aliquot TCGA-D8-A4Z1-01A-21D-A25Q-09) from TCGA case TCGA-D8-A4Z1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.7 years (25,097 days).
Specimen TCGA-D8-A4Z1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8cc13a3-f04b-4353-9da0-db1549244346.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A4Z1-10A (Blood Derived Normal), aliquot TCGA-D8-A4Z1-10A-01D-A25Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e985ad03-5b03-40c5-963c-7abb3d036f54

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 31, Silent 13, Nonsense Mutation 5, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1531-1G>A p.X511_splice | Splice Site (SNP) | VAF 5/65 reads (8%) | hotspot (GDC flag); catalogued as COSV59536648, COSV59540425, COSV59548961; called by muse, mutect2
- BDP1 | c.6065G>C p.S2022T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.889); catalogued as COSV62429012; called by muse, mutect2, varscan2
- C6orf15 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV52539079, COSV99457339; called by muse, mutect2
- CDH7 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV59884853; called by muse, mutect2
- COASY | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99888862; called by muse, mutect2
- DFFA | c.425C>G p.S142* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV65476924, COSV65477002; called by muse, mutect2, varscan2
- DOCK6 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs1224524375, COSV53911710; called by muse, mutect2
- EEF1A1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV58548609, COSV58550358; called by muse, mutect2, varscan2
- ELOB | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99241456; called by muse, mutect2
- FAR1 | c.1048C>G p.H350D | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100701676, COSV61386646; called by muse, mutect2
- FBXO46 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100480462; called by muse, mutect2
- FCN1 | c.393G>T p.W131C | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878983; called by muse, mutect2
- FGF8 | c.480G>C p.Q160H (on ENST00000344255 / NM_033164.4; = p.Q142H on NM_006119.6) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1306822945, COSV60142688, COSV60143440; called by muse, mutect2
- FOXA1 | c.678C>G p.D226E | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV99163969; called by muse, mutect2
- GANAB | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs773537449, COSV60461876; called by mutect2, varscan2
- HMCN1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54878346; called by muse, mutect2, varscan2
- KCNB2 | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV73050378; called by muse, mutect2
- LACC1 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs1015942417; called by muse, mutect2
- MAGT1 | c.314G>A p.R105Q (on ENST00000618282 / NM_001367916.1; = p.R137Q on NM_032121.5) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); catalogued as rs782076867; called by muse, mutect2
- MBD6 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV63076714; called by mutect2, varscan2
- PCDHB6 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs781817379, COSV99172544; called by muse, mutect2
- PDE12 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100239721, COSV60818144; called by muse, mutect2
- PLXNA2 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as COSV100886109; called by muse, mutect2
- PODN | c.1543G>A p.A515T (on ENST00000395871; = p.A467T on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV100439890; called by muse, mutect2
- REXO5 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV54471956; called by muse, mutect2
- SNAI3 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100178985; called by muse, mutect2
- STXBP6 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1166080816, COSV100122276; called by muse, mutect2, varscan2
- TAB3 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV55834460; called by muse, mutect2
- XPR1 | c.1005C>A p.F335L | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100851532; called by muse, mutect2
- AARS1 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ALLC | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARFGEF3 | c.2347C>G p.Q783E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.073); called by muse, mutect2
- BCDIN3D | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- CFI | c.1430-1G>C p.X477_splice | Splice Site (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- CTDSPL | c.385G>C p.D129H (on ENST00000273179 / NM_001008392.2; = p.D118H on NM_005808.3) | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HAUS6 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HK1 | c.2680G>C p.E894Q | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZAN | c.5968G>A p.E1990K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- ATP1A4 | c.444C>T p.V148= | Silent (SNP) | VAF 9/199 reads (5%) | called by muse, mutect2
- COASY | c.639C>T p.V213= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1211381712, COSV55897535; called by muse, mutect2, varscan2
- CTNNA3 | c.1488C>T p.A496= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs774425528, COSV65554396; called by muse, mutect2, varscan2
- DNAH8 | c.5208C>T p.L1736= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100547372; called by muse, mutect2
- FYCO1 | c.4257C>T p.L1419= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV99946359; called by muse, mutect2
- MAN2C1 | c.1368C>T p.A456= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- MSRA | c.90C>T p.I30= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV100412627; called by muse, mutect2
- OR6S1 | c.234C>T p.V78= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV57837588; called by muse, mutect2
- PSMC3IP | c.243G>A p.V81= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs1207183603, COSV53816146, COSV99519120; called by muse, mutect2, varscan2
- SKI | c.1686C>T p.F562= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs1446861936, COSV101049673; called by muse, mutect2
- SYBU | c.705C>T p.Y235= (on ENST00000276646 / NM_001099754.2; = p.Y234= on NM_017786.6) | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- TEX14 | c.2640G>A p.Q880= (on ENST00000240361 / NM_001201457.2; = p.Q874= on NM_031272.5) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV53611974; called by muse, mutect2, varscan2
- ZNFX1 | c.4578C>G p.L1526= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs953211375, COSV100872706; called by muse, mutect2
